Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0M9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0M9-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: GALLBLADDER, LAPAROSCOPIC CHOLECYSTECTOMY -

- A. CHRONIC CHOLECYSTITIS WITH CALCIFICATION OF WALL CONSISTENT WITH PORCELAIN GALLBLADDER.
- B. CHOLECYSTOLITHIASIS.

PART 2: UTERUS AND CERVIX (134.0 GRAMS) WITH BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY-

- A. CHRONIC CERVICITIS WITH SQUAMOUS METAPLASIA, REACTIVE EPITHELIAL ATYPIA AND CALCIFICATIONS ASSOCIATED WITH METAPLASTIC GLANDS, NO NEOPLASM IDENTIFIED.
- B. MODERATELY DIFFERENTIATED ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, FIGO GRADE 2, NUCLEAR GRADE 1.
- C. NEOPLASM INVADDES 75% OF MYOMETRIUM.
- D. NEOPLASM OCCUPIES NEARLY 100% OF ENDOMETRIAL SURFACE.
- E. PATHOLOGIC STAGE pT1c, N0, MX.
- F. LYMPHOVASCULAR INVASION IDENTIFIED, FOCAL.
- G. CYSTIC ATROPHY OF NON-NEOPLASTIC ENDOMETRIUM.
- H. OVARY WITH INCLUSION CYSTS, LEFT.
- I. UNREMARKABLE OVARY, RIGHT.
- J. UNREMARKABLE FALLOPIAN TUBES, BILATERAL.

100-0-3

Adenocarcinoma, Endometrioid, NOS
8380/3

PART 3: LYMPH NODES, LEFT EXTERNAL ILIAC, DISSECTION - ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).

Site: Endometrium
c54.1

PART 4: LYMPH NODES, LEFT OBTURATOR, DISSECTION - TWO LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/2).

hw
5/3/11

PART 5: LYMPH NODES, RIGHT EXTERNAL ILIAC, DISSECTION - TWO LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/2).

PART 6: LYMPH NODES, RIGHT OBTURATOR, DISSECTION - SOFT TISSUE, NO LYMPH NODES IDENTIFIED.

PART 7: LYMPH NODES, RIGHT COMMON ILIAC, DISSECTION - SOFT TISSUE. NO LYMPH NODES IDENTIFIED.

PART 8: LYMPH NODES, RIGHT PERIAORTIC, DISSECTION - TWO LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/2).

PART 9: LYMPH NODES, LEFT PERIAORTIC, DISSECTION - TWO LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/2).

COMMENT:

Correlated with companion pelvic wash fluid cytology interpreted as negative.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS
TUMOR TYPE: Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:
Moderately differentiated (FIGO 2)

ARCHITECTURAL GRADE: Moderately differentiated
NUCLEAR GRADE: Grade 2

TUMOR SIZE: Maximum dimension: 4.5 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

DEPTH OF INVASION**: Anterior endomyometrium: 99 %, Posterior endomyometrium: 99 %

MARGINS OF RESECTION: Greater than 1/2 thickness of myometrium

ANGIOLYMPHATIC INVASION: Vaginal margin is negative for tumor

LYMPH NODES POSITIVE: Yes

LYMPH NODES EXAMINED: Number of lymph nodes positive: 0

T STAGE, PATHOLOGIC: Total number of lymph nodes examined: 9

N STAGE, PATHOLOGIC: pT1c

M STAGE, PATHOLOGIC: pN0

FIGO STAGE: pMX

RESIDUAL TUMOR: IC

R0

Source: NCI Genomic Data Commons file 6f7a741e-544a-473d-b045-1576d7b96f66 (TCGA-BG-A0M9.08D832C7-9B5F-4B6E-9C3E-2F3E58305016.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).